Gene-level copy-number profile of tumor specimen TCGA-24-2297-01A from TCGA case TCGA-24-2297, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 56.1 years (20,487 days).
Specimen TCGA-24-2297-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file TCGA-OV.1d8caa41-37c3-4a40-8d3e-bb356efdbb77.absolute_liftover.gene_level_copy_number.v36.tsv, workflow ABSOLUTE segment calls lifted over to GRCh38 (Affymetrix SNP 6.0); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 5,714 have no estimate.
https://portal.gdc.cancer.gov/files/759dbcb6-2fe4-4ccf-a5a1-2d9855838d33

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 60; copy number 1: 12,497; copy number 2: 36,486; copy number 3: 4,803; copy number 4: 1,063.
ABSOLUTE estimates for this specimen (TCGA Pan-Cancer Atlas, from the SNP 6.0 array, sample TCGA-24-2297-01): tumor purity 0.99, ploidy 1.94, whole-genome doublings 0 (call status: legacy_call).

Homozygous deletions (total copy number 0; autosomes only): 60 genes in 4 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:150,078,445–150,257,438, 2 genes (within-gene range 0–1): DCLK2, RNU7-194P.
- chr5:58,453,982–58,863,414, 9 genes: PLK2, GAPT, AC008814.1, MIR548AE2, LINC02108, RAB3C, AC016642.1, RPL5P15, AC008852.1.
- chr5:59,039,761–59,063,503, 1 gene: AC092343.1.
- chr10:86,630,825–87,863,533, 48 genes (within-gene range 0–2): RPL7AP8, OPN4, LDB3, AC067750.1, BMPR1A, RPAP2P1, RNU1-19P, MMRN2, AC025268.1, SNCG, ADIRF-AS1, ADIRF, AL136982.7, AGAP11, BMS1P3, AL136982.1, AL136982.6, AL136982.4, AL136982.2, FAM25A, AL136982.5, RNU6-529P, GLUD1, SHLD2, AL136982.3, RN7SL733P, NUTM2A-AS1, AL157893.2, AL157893.1, NUTM2A, LINC00863, NUTM2D, NPAP1P3, CTSLP1, FAM245A, AL355334.1, AL355334.2, MIR4678, MINPP1, AL138767.2, AL138767.3, AL138767.1, RPS26P38, PAPSS2, ATAD1, CFL1P1, RN7SL78P, KLLN.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 12,497. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
